Gene-level copy-number profile of tumor specimen TCGA-13-0899-01A from TCGA case TCGA-13-0899, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.3 years (22,031 days).
Specimen TCGA-13-0899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b7573c04-ffcc-4757-833c-afdab85ac718.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0899-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d32040cc-eb0e-4596-a426-477e0c5e2bbd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 181; copy number 2: 2,894; copy number 3: 18,532; copy number 4: 20,736; copy number 5: 8,911; copy number 6: 5,906; copy number 7: 1,423; copy number 8: 51; copy number 10: 341; copy number 11: 598; copy number 14: 19; copy number 23: 114; copy number 24: 9; copy number 28: 4; copy number 38: 65; copy number 61: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0899-01A-01D-0399-01): tumor purity 0.76, ploidy 4.13, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,180 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:32,231,849–33,390,935, 23 genes, copy number 10: RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2.
- chr11:73,214,998–82,733,864, 202 genes, copy number 14–38 (broad region; genes not listed).
- chr12:66,767–32,756,463, 827 genes, copy number 10–11 (broad region; genes not listed).
- chr18:47,390–1,310,018, 39 genes, copy number 24–61 (within-gene range 7–61): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3.
- chr19:22,243,254–24,163,425, 89 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 181. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
